Somatic mutation profile of tumor specimen HCM-CSHL-0608-C17-06A (aliquot HCM-CSHL-0608-C17-06A-11D-A79M-36) from HCMI case HCM-CSHL-0608-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical carcinoid tumor; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 39.8 years (14,534 days).
Specimen HCM-CSHL-0608-C17-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 740b6cb7-393e-4087-8565-7549251d0961.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0608-C17-10A (Blood Derived Normal), aliquot HCM-CSHL-0608-C17-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5270e40-eb17-4a46-99b2-4838d5532b69

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4066C>A p.P1356T | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV101166064; called by muse, mutect2, varscan2
- AFF3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745357528, COSV100420029; called by muse, mutect2, varscan2
- AHNAK2 | c.12835C>T p.R4279W | Missense Mutation (SNP) | VAF 223/619 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs536680955, COSV60916830; called by muse, mutect2, varscan2
- AMBRA1 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 159/235 reads (68%) | catalogued as rs1354023827; called by muse, mutect2, varscan2
- AMOTL2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369381825; called by muse, mutect2, varscan2
- ARID2 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57596651, COSV57609951; called by muse, mutect2, varscan2
- ARID2 | c.4888C>T p.Q1630* | Nonsense Mutation (SNP) | VAF 120/276 reads (43%) | catalogued as COSV57599876; called by muse, mutect2, varscan2
- C8A | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs753968787, COSV63486112; called by muse, mutect2, varscan2
- CDKN1B | c.593C>G p.T198R | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1197510010; called by muse, mutect2, varscan2
- DHX15 | c.2024G>C p.R675P | Missense Mutation (SNP) | VAF 227/422 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100391765; called by muse, mutect2, varscan2
- DXO | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 51/433 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV61715311; called by muse, mutect2, varscan2
- LRRK2 | c.6677T>G p.V2226G | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV54148509; called by muse, mutect2, varscan2
- MUC5B | c.11207G>C p.G3736A | Missense Mutation (SNP) | VAF 168/756 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as rs769841042; called by muse, varscan2
- PCNX1 | c.5882G>A p.R1961H | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1162809392; called by muse, mutect2
- PRKCD | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 130/321 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs781980599, COSV57848431; called by muse, mutect2, varscan2
- SLC19A3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367620430; called by muse, mutect2, varscan2
- SULF2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 222/505 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs190217262, COSV63414310; called by muse, mutect2, varscan2
- SYNE4 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 157/396 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1396321904; called by muse, mutect2, varscan2
- TAF1 | c.4502C>A p.A1501E (on ENST00000373790 / NM_138923.4; = p.A1522E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV99336627; called by muse, mutect2, varscan2
- UGGT1 | c.1697A>G p.H566R | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs780808948; called by muse, mutect2
- ZC3H12B | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs777379401, COSV100161642; called by muse, mutect2
- ZMAT4 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 147/341 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.092); catalogued as COSV52688967; called by muse, mutect2, varscan2
- BAG6 | c.1442C>A p.T481N | Missense Mutation (SNP) | VAF 182/469 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- BCLAF3 | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH10 | c.11713G>A p.A3905T (on ENST00000409039; = p.A3844T on NM_207437.3) | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, varscan2
- LZTS2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 125/531 reads (24%) | called by muse, varscan2
- RAB38 | c.336A>C p.L112F | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- RUBCN | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 171/419 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACER2 | c.78C>T p.I26= | Silent (SNP) | VAF 193/491 reads (39%) | catalogued as rs142611269; called by muse, mutect2, varscan2
- CHST3 | c.438G>A p.S146= | Silent (SNP) | VAF 104/606 reads (17%) | called by muse, mutect2, varscan2
- ELAC1 | c.933G>A p.L311= | Silent (SNP) | VAF 37/449 reads (8%) | called by muse, mutect2
- ESX1 | c.624T>G p.T208= | Silent (SNP) | VAF 234/568 reads (41%) | called by muse, mutect2, varscan2
- FBXL19 | c.1827C>T p.H609= | Silent (SNP) | VAF 129/699 reads (18%) | catalogued as rs531482894; called by muse, mutect2, varscan2
- MUC5B | c.11064G>A p.G3688= | Silent (SNP) | VAF 280/712 reads (39%) | called by muse, varscan2
- RASGRP4 | c.1200C>T p.S400= | Silent (SNP) | VAF 29/418 reads (7%) | catalogued as rs779453932; called by muse, mutect2
- WNT9A | c.552C>A p.G184= | Silent (SNP) | VAF 66/458 reads (14%) | called by muse, mutect2, varscan2
- ZC3H7B | c.702G>A p.L234= | Silent (SNP) | VAF 108/722 reads (15%) | called by muse, mutect2, varscan2
- ZNF536 | c.1908C>T p.C636= | Silent (SNP) | VAF 200/472 reads (42%) | catalogued as rs763902544, COSV100835870, COSV62822641; called by muse, mutect2, varscan2
- ZSCAN10 | c.1941C>T p.N647= (on ENST00000252463; = p.N702= on NM_032805.3) | Silent (SNP) | VAF 54/880 reads (6%) | catalogued as rs573961182, COSV52967891; called by muse, mutect2
- CARMIL3 | c.2707-104C>T | Intron (SNP) | VAF 42/550 reads (8%) | called by muse, mutect2
- KCNQ1 | c.1514+3088G>T | Intron (SNP) | VAF 110/296 reads (37%) | called by muse, mutect2, varscan2
